Somatic mutation profile of tumor specimen MP2PRT-PASSDM-TMP1-A (aliquot MP2PRT-PASSDM-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASSDM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,424 days).
Specimen MP2PRT-PASSDM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b695df5-06e3-46a2-99a0-0db28c54d530.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSDM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSDM-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60643c00-07cc-44e6-94f3-003fb1433b1f

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 91/409 reads (22%) | catalogued as rs764466442, CM014518, COSV64405911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 124/309 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AXIN2 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 189/615 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61059009; called by muse, mutect2, varscan2
- CADPS2 | c.2206G>A p.V736I | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as rs1468357178; called by muse, mutect2
- CCSER1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422192912; called by muse, mutect2
- CEP76 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 88/506 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1237794359; called by muse, mutect2, varscan2
- COL6A5 | c.7501G>A p.E2501K (on ENST00000312481; = p.E2497K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs200982668; called by muse, mutect2, varscan2
- CYP4B1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs1440319489, COSV54720958, COSV54726208; called by muse, mutect2, varscan2
- DYSF | c.4978G>A p.G1660S | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375068646; ClinVar: uncertain significance; called by muse, mutect2
- NAALAD2 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.302); catalogued as rs765151836, COSV58958409, COSV58958544, COSV58966822; called by muse, mutect2
- NEBL | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs727504979, COSV65806409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as rs777394177, COSV65059757; called by muse, mutect2, varscan2
- SYT7 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 143/413 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1441820938; called by muse, mutect2, varscan2
- TYRP1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758005695; called by muse, mutect2, varscan2
- CREBBP | c.4610T>C p.L1537P | Missense Mutation (SNP) | VAF 174/480 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-7 | chr14:106062149 TCTCTCGCAC>GTTCCTAA | Missense Mutation (DEL) | VAF 29/75 reads (39%) | called by pindel, varscan2*
- IGKV1D-8 | chr2:90221382 TCCCACAGTGTT>CTTTCGAG | Missense Mutation (DEL) | VAF 29/60 reads (48%) | called by pindel, varscan2*
- MED12L | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NOC4L | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- NPR3 | c.1540A>T p.R514W (on ENST00000265074 / NM_001364458.2; = p.R513W on NM_000908.4) | Missense Mutation (SNP) | VAF 61/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP214 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- SH2B3 | c.1192dup p.R398Pfs*58 | Frame Shift Ins (INS) | VAF 46/238 reads (19%) | called by mutect2, varscan2
- SH2B3 | c.1193G>C p.R398P | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by mutect2, varscan2
- SOX3 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2
- ABCA12 | c.882G>T p.L294= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV55968818; called by muse, mutect2
- APBA2 | c.2223G>A p.T741= | Silent (SNP) | VAF 109/410 reads (27%) | catalogued as rs761106891; called by muse, mutect2, varscan2
- COL6A5 | c.1074G>A p.A358= | Silent (SNP) | VAF 79/336 reads (24%) | catalogued as rs965535228, COSV55196460; called by muse, mutect2, varscan2
- MPRIP | c.2652C>A p.G884= | Silent (SNP) | VAF 28/374 reads (7%) | catalogued as COSV57927560; called by muse, mutect2
- MUC17 | c.6762T>C p.S2254= | Silent (SNP) | VAF 24/376 reads (6%) | called by muse, mutect2
- OPN5 | c.579G>A p.S193= | Silent (SNP) | VAF 62/658 reads (9%) | catalogued as rs558057158, COSV55244308, COSV55247257; called by muse, mutect2
- ZXDA | c.2122T>C p.L708= | Silent (SNP) | VAF 121/310 reads (39%) | called by muse, mutect2, varscan2
- ENPP2 | c.973-2023G>A | Intron (SNP) | VAF 84/374 reads (22%) | catalogued as rs201799245; called by muse, mutect2, varscan2
